Gene-level copy-number profile of tumor specimen ALCH-B3GD-TTP1-A from ALCHEMIST case ALCH-B3GD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.7 years (26,542 days).
Specimen ALCH-B3GD-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 23dd96ff-ace0-48b6-9f2b-6a879bd6c448.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3GD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/81213a4d-a414-4535-94c8-43a3d273b909

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 7,342; copy number 2: 48,876; copy number 3: 2,203; copy number 4: 405; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:3,156,756–3,157,797, 1 gene: AC019118.1.
- chr2:47,939,738–47,940,218, 1 gene: PPIAP62.
- chr2:52,570,648–52,572,522, 1 gene: CRTC1P1.
- chr2:89,252,211–89,254,015, 2 genes: IGKV3-31, IGKV1-32.
- chr2:89,309,898–89,600,680, 4 genes: IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:132,253,154–132,263,042, 3 genes (within-gene range 0–2): RNA5-8SP5, MIR663B, CDC27P1.
- chr4:173,615,936–173,634,371, 2 genes: MORF4, RANP6.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:50,409,042–54,725,816, 12 genes: AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr12:38,078,529–38,087,392, 2 genes: AK6P2, CLUHP8.
- chr15:97,272,020–97,319,321, 1 gene (within-gene range 0–2): AC020704.1.
- chr19:27,638,483–27,646,483, 2 genes: ERVK-28, AC112702.1.
- chr21:10,640,028–10,649,835, 2 genes: AF254982.1, IGHV1OR21-1.
- chr22:29,554,808–29,581,327, 1 gene (within-gene range 0–2): NIPSNAP1.
- chr22:35,400,134–35,425,431, 1 gene: MCM5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:63,848,261–63,848,362, 1 gene, copy number 5: Y_RNA.
- chr20:63,738,270–63,744,050, 2 genes, copy number 5 (within-gene range 2–5): AL121845.2, SLC2A4RG.

Autosomal genes at a single copy (total copy number 1): 4,531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
